Surgical pathology report (de-identified scan), TCGA case TCGA-BR-7715, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-7715-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

Asterand Case ID	Open Clinica Subject ID	TCGA	Gross Description	Microscopic Description	Diagnosis Details
		BR-7715			

[page 2 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy

Tumor site: Stomach

Tumor size: 5 x 5 x 1 cm

Tumor features: None specified

Histologic type:

Adenocarcinoma

Histologic grade: Moderately differentiated

Tumor extent: Subserosa

Lymph nodes: 0/9 positive for metastasis (Regional 0/9)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Perineural invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings:
Not specified

Comments: None

Date of Procurement

Journal Pre-proof

Source: NCI Genomic Data Commons file e3c55e0c-2e69-45eb-8d1e-1f934184824d (TCGA-BR-7715.20D6AD35-408C-4E2B-AD21-9463C3F430C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).